Surgical pathology report (de-identified scan), TCGA case TCGA-D7-A747, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-A747-01A (Primary Tumor).

Patient: XXX

Age:

Gender: M

Examination result No.

Unit in charge:

Physician in charge:

Clinical diagnosis (suspicion)

Date of admission:

ICD-O-3
Adenocarcinoma, diffuse type
C64.0
Site Gastric antrum
path
Prepyloric C16.4
8/14/13
C16.3

Material:

1) Material: stomach, stomach with a tumour in the prepyloric region and involved part of the pancreas. Method of collection: Total organ resection

9/26/13

Histopathological diagnosis:

Examination performed on:

Poorly differentiated gastric carcinoma.

Metastases in 2/8 adjacent lymph nodes.

G3, pT3, pN1. (8010/3 T-63000)*

* codes according to ICD-O-3 or SNOMED

Macroscopic description:

Stomach sized: 13 x 16cm with the omentum sized 24 x 18cm. Part of pancreas sized 4 x 2 x 1.8cm. The mucosa exhibiting an ulcerated tumour of 3.5 x 3 x 1.2cm. The lesion is located 8.5cm away from the proximal incision line, and 1.0cm from the distal one.

Microscopic description:

Poorly differentiated gastric cancer (G3 acc. to Lauren, diffuse type). The tumour infiltrating the fat tissue of the lesser curvature (pT3) and the greater omentum. Incision lines free of neoplastic lesions. Metastases to lymph nodes (2/8) and cancer embolism in the vessels.

Assistant:

Pathologist:

Edited by

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 77a1ec3e-2445-4546-a15c-31fd31d2ab63 (TCGA-D7-A747.4AF2569D-B00E-4F78-A0A8-98141C34827C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).